Somatic mutation profile of tumor specimen TCGA-55-8089-01A (aliquot TCGA-55-8089-01A-11D-2238-08) from TCGA case TCGA-55-8089, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 56.3 years (20,576 days).
Specimen TCGA-55-8089-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67b52888-d1ea-40f9-b4dd-38ccb8aa949f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8089-10A (Blood Derived Normal), aliquot TCGA-55-8089-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3e2dcfc-552c-41fc-855b-b7e7e1019df0

The open-access MAF lists 1,322 somatic variants for this specimen: 995 protein-altering or splice-affecting, 293 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 877, Silent 293, Nonsense Mutation 67, Splice Site 24, Intron 14, RNA 12, Frame Shift Del 11, Splice Region 10, Frame Shift Ins 5, 5'UTR 3, 3'UTR 2, 5'Flank 2.

Variants (750 of 1,322; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.1347+1G>A p.X449_splice | Splice Site (SNP) | VAF 16/83 reads (19%) | catalogued as rs397509370, CS1412507, CS143082, CS900238, COSV58587081; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KIF1C | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777198, CM140690, COSV57905940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- A1BG | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs532938564, COSV54052573; called by muse, varscan2
- A2M | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV59385937; called by muse, mutect2, varscan2
- A2ML1 | c.3229G>T p.A1077S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.158); catalogued as COSV55295427; called by muse, mutect2
- A2ML1 | c.3778G>C p.E1260Q | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.776); catalogued as COSV55289222, COSV55295444; called by muse, mutect2, varscan2
- ABCA6 | c.4465G>T p.G1489* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV52642256; called by muse, mutect2, varscan2
- ABCC12 | c.2617T>G p.F873V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60916504; called by muse, mutect2, varscan2
- ABCC12 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV60916513; called by muse, varscan2
- ABCC12 | c.1909G>T p.V637L | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs147110729, COSV60916547; called by muse, varscan2
- ABCC8 | c.2473C>A p.R825= | Splice Region (SNP) | VAF 30/206 reads (15%) | catalogued as rs779736828, CM073979, COSV56846548, COSV56854820; called by muse, mutect2, varscan2
- ABCC9 | c.3789T>A p.N1263K | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53980235; called by muse, mutect2, varscan2
- ABCF2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 49/298 reads (16%) | catalogued as COSV55185159; called by muse, mutect2, varscan2
- ABHD1 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as COSV53207397, COSV53208368, COSV99574408; called by muse, mutect2, varscan2
- ABLIM3 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV58646703; called by muse, mutect2, varscan2
- ABRA | c.158C>A p.P53Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61733103; called by muse, varscan2
- AC006059.2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59608531; called by muse, mutect2, varscan2
- ACER1 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV56836353; called by muse, mutect2, varscan2
- ACKR2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1208059580, COSV56179103; called by muse, mutect2, varscan2
- ACKR3 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.192); catalogued as COSV56021991, COSV56022941; called by muse, mutect2, varscan2
- ACTR8 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51637861; called by muse, mutect2
- ADAD1 | c.848G>T p.R283M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56645710; called by muse, mutect2, varscan2
- ADAM19 | c.1207T>A p.C403S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57435445; called by muse, mutect2, varscan2
- ADAM33 | c.1487C>G p.P496R | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598000, COSV100598089; called by muse, mutect2
- ADAMTS2 | c.2617G>A p.G873R | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52366464, COSV52385382; called by muse, mutect2, varscan2
- ADAMTS5 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53179331; called by muse, mutect2, varscan2
- ADCY5 | c.1788G>T p.E596D | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59201497; called by muse, mutect2, varscan2
- ADGRA2 | c.2414G>T p.W805L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV99605132; called by muse, mutect2
- ADGRB1 | c.3240G>C p.M1080I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV60101335; called by muse, mutect2, varscan2
- ADGRG4 | c.8812G>T p.D2938Y | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54954414, COSV54962817; called by muse, mutect2, varscan2
- ADGRG6 | c.1307G>A p.W436* | Nonsense Mutation (SNP) | VAF 24/125 reads (19%) | catalogued as COSV51597881; called by muse, mutect2, varscan2
- ADGRL2 | c.2119A>T p.N707Y (on ENST00000370717 / NM_001366005.1; = p.N694Y on NM_012302.4) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV99591619; called by muse, mutect2, varscan2
- ADGRV1 | c.8430T>A p.Y2810* | Nonsense Mutation (SNP) | VAF 21/223 reads (9%) | catalogued as COSV67991448; called by muse, mutect2, varscan2
- ADGRV1 | c.18217G>T p.V6073L | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67991452; called by muse, mutect2, varscan2
- AFF1 | c.2406G>C p.R802S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV57122430, COSV57123197; called by muse, mutect2
- AFF2 | c.1758G>T p.R586S | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV54000142; called by muse, mutect2, varscan2
- AGAP2 | c.1373G>A p.R458Q (on ENST00000547588 / NM_001122772.2; = p.R122Q on NM_014770.4) | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs746174895, COSV57728674; called by muse, mutect2, varscan2
- AGAP4 | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV71165025; called by muse, mutect2, varscan2
- AGPAT1 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV61248330; called by muse, mutect2, varscan2
- AGPAT1 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV61248336; called by muse, mutect2
- AGPAT1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61248340; called by muse, mutect2, varscan2
- AHCTF1 | c.3986G>T p.G1329V (on ENST00000366508; = p.G1303V on NM_015446.5) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV58253162; called by muse, mutect2, varscan2
- AHNAK2 | c.6919G>A p.A2307T | Missense Mutation (SNP) | VAF 123/523 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as rs182618947, COSV100318990; called by muse, mutect2, varscan2
- AHNAK2 | c.2042A>T p.K681M | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1313387071, COSV60923889; called by muse, mutect2
- AIFM2 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV57160207; called by muse, mutect2, varscan2
- AKAP4 | c.2172G>T p.L724F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV62075022; called by muse, mutect2, varscan2
- AKNA | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.036); catalogued as rs549404488, COSV56314100; called by muse, mutect2, varscan2
- ALG12 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | PolyPhen probably damaging (1); catalogued as COSV58207989; called by muse, mutect2, varscan2
- ALK | c.3350C>A p.T1117N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV66581798; called by muse, mutect2, varscan2
- ALPI | c.92G>A p.W31* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV55015603; called by muse, mutect2, varscan2
- AMER1 | c.3364A>T p.T1122S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV57664770; called by muse, mutect2, varscan2
- AMER3 | c.1514C>T p.T505I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58468684; called by muse, mutect2, varscan2
- ANK1 | c.4604T>A p.L1535Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV55889608; called by muse, mutect2, varscan2
- ANK2 | c.4732G>T p.V1578L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV52177782; called by muse, mutect2, varscan2
- ANK3 | c.5389G>T p.A1797S | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.009); catalogued as COSV55043466, COSV55072089; called by muse, mutect2, varscan2
- ANKIB1 | c.1778A>C p.Q593P | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56064329; called by muse, mutect2
- ANKK1 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262668152, COSV58273360; called by muse, mutect2
- ANKRD17 | c.5040T>G p.S1680R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as COSV58225102; called by muse, mutect2, varscan2
- ANKRD23 | c.393G>C p.L131F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58413102; called by muse, mutect2, varscan2
- ANKRD30A | c.2748G>C p.K916N (on ENST00000611781; = p.K860N on NM_052997.2) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV64616511, COSV64617364; called by muse, mutect2, varscan2
- ANKRD50 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as COSV72385297; called by muse, mutect2, varscan2
- ANKS1A | c.2564A>G p.Q855R | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV64462882; called by muse, mutect2
- AP1G2 | c.1492C>G p.P498A | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV55339225; called by muse, mutect2, varscan2
- AP4M1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57997982; called by muse, mutect2, varscan2
- APOA5 | c.1043G>T p.W348L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57064183; called by muse, mutect2, varscan2
- ARFGEF1 | c.3799C>T p.Q1267* | Nonsense Mutation (SNP) | VAF 29/197 reads (15%) | catalogued as COSV51613996, COSV99144732; called by muse, mutect2, varscan2
- ARFGEF1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.631); catalogued as COSV51614014; called by muse, mutect2
- ARHGAP33 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV50140534; called by muse, mutect2, varscan2
- ARHGAP35 | c.3879G>C p.E1293D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV68333968; called by muse, mutect2, varscan2
- ARID1A | c.4735C>T p.Q1579* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV61371921; called by muse, mutect2, varscan2
- ARID1B | c.3557G>C p.G1186A | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV51673349; called by muse, mutect2, varscan2
- ARID2 | c.1911A>T p.A637= | Splice Region (SNP) | VAF 42/192 reads (22%) | catalogued as COSV57610727; called by muse, mutect2, varscan2
- ARMC5 | c.475+1G>T p.X159_splice | Splice Site (SNP) | VAF 15/129 reads (12%) | catalogued as COSV51657284, COSV51658704; called by muse, mutect2, varscan2
- ASB4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as COSV99987243; called by muse, mutect2, varscan2
- ASH1L | c.7525G>A p.E2509K (on ENST00000368346 / NM_001366177.2; = p.E2504K on NM_018489.3) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV64211470; called by muse, mutect2, varscan2
- ASIC2 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as COSV63320354; called by muse, mutect2, varscan2
- ASIC3 | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV52524737; called by muse, mutect2, varscan2
- ATG101 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.285); catalogued as COSV61085535; called by muse, mutect2, varscan2
- ATP10B | c.2634G>C p.E878D | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59160371; called by muse, mutect2, varscan2
- ATP10D | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV56710851, COSV56712027; called by muse, mutect2
- ATP13A5 | c.1558G>C p.A520P | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as COSV60872640; called by muse, mutect2, varscan2
- ATP1A2 | c.355A>T p.M119L | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV63405063; called by muse, mutect2, varscan2
- ATP6V0E2 | c.226G>C p.V76L (on ENST00000425642; = p.V125L on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776613281, COSV101374605, COSV70416501; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1483G>T p.D495Y | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1558681213, COSV52270837; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1B2 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs1490590011, COSV52354574; called by muse, mutect2, varscan2
- ATP7A | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM970136, COSV58451007; called by muse, mutect2, varscan2
- ATP8A1 | c.594+1G>C p.X198_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as COSV52542893; called by mutect2, varscan2
- ATP8B1 | c.2720G>T p.G907V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52178508; called by muse, mutect2, varscan2
- ATXN7 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as COSV55754030; called by muse, mutect2, varscan2
- ATXN7 | c.2228G>C p.G743A | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.319); catalogued as rs778772939, COSV55754061; called by muse, mutect2, varscan2
- B2M | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 13/117 reads (11%) | catalogued as COSV62563151; called by muse, mutect2, varscan2
- B4GALNT2 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55927528; called by muse, mutect2, varscan2
- BACH1 | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54520199; called by muse, mutect2, varscan2
- BCOR | c.2482G>A p.A828T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV60699711; called by muse, mutect2, varscan2
- BDP1 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV100702759, COSV62433142; called by muse, mutect2, varscan2
- BEST3 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV58303523, COSV58303736; called by muse, mutect2, varscan2
- BMPER | c.1918C>A p.P640T | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51826737; called by muse, mutect2, varscan2
- BORA | c.1309G>T p.E437* (on ENST00000613797; = p.E362* on NM_024808.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/173 reads (23%) | catalogued as COSV100909776, COSV64695732; called by muse, mutect2, varscan2
- BORA | c.1310A>T p.E437V (on ENST00000613797; = p.E362V on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV100909777; called by muse, mutect2, varscan2
- BPIFC | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55914591; called by muse, mutect2, varscan2
- BPIFC | c.264T>A p.F88L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.918); catalogued as COSV55914609; called by muse, mutect2, varscan2
- BRD7 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV67159613; called by muse, mutect2, varscan2
- BRD9 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.766); catalogued as rs1307014886, COSV60245437; called by muse, mutect2
- BSN | c.11075C>A p.P3692Q | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56523943; called by muse, mutect2, varscan2
- BUB1 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs746460291, COSV57065792; called by muse, mutect2, varscan2
- C12orf4 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV54207236, COSV54208611; called by muse, mutect2, varscan2
- C1orf141 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV63992794; called by muse, mutect2, varscan2
- CA3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.065); catalogued as COSV53410643; called by mutect2, varscan2
- CACHD1 | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs752120721, COSV51557553; called by muse, mutect2
- CACNA1A | c.4498G>A p.V1500M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64206289; called by muse, mutect2, varscan2
- CACNA2D4 | c.285C>A p.Y95* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV54956048; called by muse, mutect2, varscan2
- CACNG7 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as COSV55816209, COSV99712051; called by muse, mutect2, varscan2
- CAD | c.5503G>C p.E1835Q | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV53030124; called by muse, mutect2, varscan2
- CALCOCO2 | c.364C>G p.P122A | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51951905, COSV51952983; called by muse, mutect2, varscan2
- CAMK4 | c.1181T>A p.L394Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV56678337; called by muse, mutect2, varscan2
- CASD1 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51974363; called by muse, mutect2, varscan2
- CASP10 | c.1393C>G p.H465D (on ENST00000272879 / NM_032974.5; = p.H422D on NM_001230.5) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV53779795; called by muse, mutect2, varscan2
- CATSPER2 | c.1411C>G p.L471V (on ENST00000321596 / NM_001282309.3; = p.L473V on NM_172095.4) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs772077547, COSV100390996; called by muse, mutect2, varscan2
- CATSPERE | c.2293G>C p.V765L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV63680245; called by muse, mutect2, varscan2
- CBLN1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99535825; called by muse, mutect2
- CCDC181 | c.830A>T p.H277L | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63157470; called by muse, mutect2, varscan2
- CCDC61 | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV54429710; called by muse, mutect2, varscan2
- CCDC70 | c.132G>A p.M44I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV54430703; called by muse, mutect2, varscan2
- CCDC8 | c.240G>C p.R80S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56774238, COSV56774812; called by muse, mutect2, varscan2
- CCDC93 | c.1184A>T p.N395I | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV60122956; called by muse, mutect2
- CCDC96 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509120; called by muse, mutect2, varscan2
- CCNB1IP1 | c.730A>T p.T244S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.056); catalogued as rs1355336104, COSV62303237; called by muse, mutect2, varscan2
- CCNH | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.944); catalogued as rs1323744504, COSV56925778; called by muse, mutect2, varscan2
- CCR1 | c.735G>A p.M245I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV56121731; called by muse, varscan2
- CCSER1 | c.1919G>T p.R640I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61451387; called by muse, mutect2
- CD163L1 | c.2207C>A p.A736E | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV58014415; called by muse, mutect2, varscan2
- CD1E | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63770403, COSV63772157; called by muse, mutect2
- CD248 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV100256752; called by muse, mutect2
- CD34 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60414303; called by muse, mutect2, varscan2
- CD47 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs753024870, COSV62527941; called by muse, mutect2, varscan2
- CD6 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 60/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57841023; called by muse, mutect2, varscan2
- CD84 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.251); catalogued as COSV60869899; called by muse, mutect2
- CDC7 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52311936; called by muse, mutect2, varscan2
- CDH3 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 86/266 reads (32%) | catalogued as COSV50564686; called by muse, mutect2, varscan2
- CDH9 | c.2039C>G p.P680R | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV50362848, COSV99142884; called by muse, mutect2, varscan2
- CDK12 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV71000531, COSV71002019; called by muse, mutect2
- CDKN2A | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV58688112, COSV58700302, COSV58725006; called by muse, mutect2, varscan2
- CDX4 | c.6C>A p.Y2* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV65171813; called by muse, mutect2, varscan2
- CEACAM4 | c.704A>T p.Q235L | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99701224; called by muse, mutect2, varscan2
- CEACAM4 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99701230; called by muse, mutect2, varscan2
- CEBPE | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201609537, COSV52830368; called by muse, mutect2, varscan2
- CELSR2 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV54776778; called by muse, mutect2, varscan2
- CEP350 | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62607235; called by muse, mutect2, varscan2
- CEP63 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV59678188; called by muse, mutect2, varscan2
- CERK | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV99348798; called by muse, mutect2
- CFAP74 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.848); catalogued as rs776642755, COSV54571115; called by muse, mutect2
- CFAP97 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV57111572; called by muse, mutect2, varscan2
- CHD1 | c.2244T>G p.F748L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV52343113; called by muse, mutect2, varscan2
- CHMP4C | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926958; called by muse, mutect2
- CHMP7 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV57533528; called by muse, mutect2, varscan2
- CHRM2 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57779436; called by muse, mutect2, varscan2
- CHRNA1 | c.1325C>T p.A442V (on ENST00000261007 / NM_001039523.3; = p.A417V on NM_000079.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV53684239; called by muse, mutect2, varscan2
- CHST15 | c.1637G>T p.R546M | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100655359; called by muse, mutect2, varscan2
- CHST2 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); catalogued as COSV58886487, COSV99046232; called by muse, mutect2, varscan2
- CIDEA | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs753389170, COSV57598616; called by muse, mutect2, varscan2
- CILP2 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52278280; called by muse, mutect2, varscan2
- CIR1 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV59597166; called by muse, mutect2, varscan2
- CLASP1 | c.4096G>A p.A1366T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV55333270; called by muse, mutect2, varscan2
- CLCA4 | c.1496G>T p.S499I | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); catalogued as COSV55369917; called by muse, mutect2
- CLCNKB | c.1751G>T p.S584I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV65153967; called by muse, mutect2
- CLDN10 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV54825562; called by muse, mutect2, varscan2
- CLDN14 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.417); catalogued as COSV59776226; called by muse, mutect2, varscan2
- CLP1 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57055356; called by muse, mutect2, varscan2
- CNPY4 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV53542982; called by muse, mutect2, varscan2
- CNTN3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV55179688, COSV55182021; called by muse, mutect2, varscan2
- CNTN6 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63182329; called by muse, mutect2, varscan2
- CNTN6 | c.2162G>T p.W721L | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100610400, COSV63172359; called by muse, mutect2
- CNTN6 | c.2163G>T p.W721C | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100611863, COSV63168994; called by muse, mutect2
- CNTNAP4 | c.2260G>T p.A754S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56692897; called by muse, mutect2, varscan2
- CNTNAP4 | c.2632C>G p.H878D | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as COSV56692911; called by muse, mutect2
- CNTNAP4 | c.3466A>T p.T1156S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as COSV56692925; called by mutect2, varscan2
- COG7 | c.1231A>T p.R411* | Nonsense Mutation (SNP) | VAF 14/106 reads (13%) | catalogued as COSV56151848; called by muse, mutect2, varscan2
- COL11A1 | c.1709C>A p.P570H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV62190780; called by muse, mutect2, varscan2
- COL15A1 | c.3594A>G p.P1198= | Splice Region (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100897538, COSV66647811; called by muse, mutect2, varscan2
- COL19A1 | c.2446-1G>A p.X816_splice | Splice Site (SNP) | VAF 16/91 reads (18%) | catalogued as COSV59580962; called by muse, mutect2, varscan2
- COL22A1 | c.4250G>T p.G1417V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57350333; called by muse, mutect2, varscan2
- COL24A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65310491; called by muse, mutect2, varscan2
- COL3A1 | c.2932G>T p.G978C | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM066013, COSV58593753; called by muse, mutect2, varscan2
- COL4A2 | c.1676G>T p.R559L | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV64631598, COSV64634010; called by muse, mutect2, varscan2
- COL5A2 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV66412517; called by muse, mutect2, varscan2
- COL7A1 | c.3702T>A p.C1234* | Nonsense Mutation (SNP) | VAF 44/229 reads (19%) | catalogued as COSV60399809; called by muse, mutect2, varscan2
- COPA | c.3624G>C p.E1208D | Missense Mutation (SNP) | VAF 92/592 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV54107000; called by muse, mutect2, varscan2
- COPS4 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52316364; called by muse, mutect2, varscan2
- CORO7 | c.1979G>T p.R660L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs556093901, COSV52032567; called by muse, mutect2, varscan2
- COX8C | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs200838169, COSV56401239, COSV99830055; called by muse, mutect2, varscan2
- CPA4 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55984434; called by muse, mutect2
- CPE | c.1201G>T p.D401Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68579486, COSV68581752; called by muse, mutect2, varscan2
- CPEB2 | c.2964G>T p.Q988H | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52594070; called by muse, mutect2, varscan2
- CPLANE2 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV65057275; called by muse, mutect2, varscan2
- CPOX | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51639228; called by muse, mutect2, varscan2
- CPZ | c.260A>C p.Q87P (on ENST00000360986 / NM_001014447.3; = p.Q76P on NM_003652.3) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV59924579; called by muse, mutect2, varscan2
- CRACD | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51727486; called by muse, mutect2, varscan2
- CREBBP | c.5624G>T p.R1875L | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV52134508; called by muse, mutect2, varscan2
- CRMP1 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61481810; called by muse, mutect2, varscan2
- CRMP1 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV61481822; called by muse, mutect2, varscan2
- CRNKL1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV55640178; called by muse, mutect2, varscan2
- CSMD1 | c.6823G>A p.D2275N (on ENST00000520002; = p.D2274N on NM_033225.6) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV59281626; called by muse, mutect2, varscan2
- CSMD3 | c.10037-1G>T p.X3346_splice (on ENST00000297405 / NM_001363185.1; = p.X3177_splice on NM_052900.3) | Splice Site (SNP) | VAF 36/201 reads (18%) | catalogued as COSV52254152, COSV52261031; called by muse, mutect2, varscan2
- CTDSP2 | c.623G>T p.R208M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66080162; called by muse, mutect2, varscan2
- CX3CR1 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV64193654, COSV64194709; called by muse, mutect2, varscan2
- CYP4F2 | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 51/275 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV50002127; called by muse, mutect2, varscan2
- CYP8B1 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV60227157; called by muse, mutect2, varscan2
- DAPK3 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as rs1025302295, COSV56663991; called by muse, mutect2, varscan2
- DCAF16 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as COSV66384316; called by muse, mutect2, varscan2
- DCLRE1B | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV56726218; called by muse, mutect2, varscan2
- DDR2 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV63372835; called by muse, mutect2, varscan2
- DDX60L | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372379599; called by muse, mutect2, varscan2
- DHX32 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV52942297; called by muse, mutect2, varscan2
- DLGAP4 | c.618C>A p.S206R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59421205; called by muse, mutect2, varscan2
- DMRTC2 | c.225G>T p.L75= | Splice Region (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99523490; called by muse, mutect2
- DNAH8 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59451537; called by muse, mutect2, varscan2
- DNAH8 | c.4939G>C p.A1647P | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59467870; called by muse, mutect2, varscan2
- DNAH9 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs201163987, COSV52365426; called by muse, mutect2, varscan2
- DNAH9 | c.4783G>A p.D1595N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs780836548, COSV52365436; called by muse, mutect2, varscan2
- DNAI4 | c.2422C>G p.L808V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1419099678, COSV64030130, COSV64030615; called by muse, mutect2, varscan2
- DNAJB1 | c.498C>A p.H166Q | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs776395351, COSV54317645; called by muse, mutect2
- DNAJB6 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV51098101; called by muse, mutect2
- DNMT3A | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53064299, COSV53067349; called by muse, mutect2, varscan2
- DOCK1 | c.788G>T p.W263L | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV99732782; called by muse, mutect2
- DOCK1 | c.3209G>T p.W1070L | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54751550; called by muse, mutect2, varscan2
- DOCK5 | c.5096C>T p.S1699L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.114); catalogued as rs762025197, COSV52407563; called by muse, mutect2, varscan2
- DOK5 | c.835G>T p.G279* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV52823309; called by muse, mutect2, varscan2
- DPY19L4 | c.736-2A>T p.X246_splice | Splice Site (SNP) | VAF 5/35 reads (14%) | catalogued as COSV68963465; called by muse, mutect2, varscan2
- DSCAM | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68024819; called by muse, mutect2, varscan2
- DSCAML1 | c.4509C>G p.D1503E (on ENST00000321322; = p.D1443E on NM_020693.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58398174; called by muse, mutect2, varscan2
- ECD | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54353472; called by muse, mutect2
- EFCAB3 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV59503667; called by muse, mutect2, varscan2
- EFCAB5 | c.1328A>T p.N443I | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV57934063; called by muse, mutect2, varscan2
- EIF3A | c.3220G>T p.D1074Y | Missense Mutation (SNP) | VAF 57/433 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV64962484; called by muse, varscan2
- EIF3B | c.1389G>C p.K463N | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100703865; called by muse, mutect2, varscan2
- EIF3E | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 18/141 reads (13%) | catalogued as COSV55204843; called by muse, mutect2, varscan2
- EIF4EBP2 | c.343C>G p.Q115E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100947069, COSV64667635; called by muse, mutect2, varscan2
- ELF1 | c.1460A>T p.Q487L | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV53501283; called by muse, mutect2, varscan2
- EML1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV51749552, COSV51750691; called by muse, mutect2, varscan2
- ENPP3 | c.2366A>G p.N789S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as COSV62953949, COSV62955537; called by muse, mutect2, varscan2
- ENTR1 | c.1036G>T p.V346L (on ENST00000357365 / NM_001039707.2; = p.V323L on NM_006643.4) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs757310160, COSV53742607; called by muse, mutect2, varscan2
- ERBIN | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV52323006; called by muse, mutect2, varscan2
- ERC1 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV61697751; called by muse, mutect2, varscan2
- ERCC6 | c.4005G>T p.R1335S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV63392845; called by muse, mutect2
- ERICH1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.37); catalogued as COSV50639916; called by muse, mutect2, varscan2
- ERICH3 | c.2453A>T p.Q818L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100445882, COSV58613592; called by muse, mutect2, varscan2
- ESF1 | c.2263-2A>T p.X755_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99176541; called by muse, mutect2
- ESPNL | c.1539G>C p.Q513H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58036801; called by muse, mutect2
- ESYT3 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.054); catalogued as COSV67441739; called by muse, mutect2, varscan2
- EXOC3L2 | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | catalogued as COSV52973985; called by muse, mutect2, varscan2
- EXOG | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as rs773281511, COSV55064212, COSV99815451; called by muse, mutect2, varscan2
- EXOG | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55064231; called by muse, mutect2, varscan2
- EXTL3 | c.2590C>G p.Q864E | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs765253435, COSV55039299; called by muse, mutect2, varscan2
- FADS6 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV59603348; called by muse, mutect2, varscan2
- FAM110B | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100826286; called by muse, mutect2
- FAM114A2 | c.496-1G>T p.X166_splice | Splice Site (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61078460; called by muse, mutect2, varscan2
- FAM160B1 | c.2118G>C p.Q706H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100985610, COSV65089049; called by muse, mutect2, varscan2
- FAM222A | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs368204588; called by muse, mutect2, varscan2
- FAM47A | c.1307G>C p.R436T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV60498761, COSV60500652; called by muse, mutect2, varscan2
- FAM47A | c.742C>G p.R248G | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100650088, COSV60499376; called by muse, mutect2, varscan2
- FAM71A | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV54236610; called by muse, mutect2, varscan2
- FAT1 | c.7349C>T p.S2450L | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.639); catalogued as COSV71673814, COSV71675311; called by muse, mutect2, varscan2
- FAT2 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs761296405, COSV55825806; called by muse, mutect2, varscan2
- FAT3 | c.12872C>T p.A4291V | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV53078352; called by muse, mutect2, varscan2
- FAT3 | c.13427C>G p.P4476R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs757499607, COSV53095195, COSV53150166; called by muse, mutect2, varscan2
- FAT4 | c.6748C>G p.L2250V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV58699716; called by muse, mutect2, varscan2
- FAT4 | c.11691G>T p.R3897S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV100630241; called by muse, mutect2
- FBLN7 | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55616224, COSV55616922; called by muse, mutect2
- FBN1 | c.3310G>A p.G1104R | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57325399; called by muse, mutect2, varscan2
- FBXO38 | c.1158C>G p.I386M | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.777); catalogued as COSV57030048; called by muse, mutect2, varscan2
- FBXO47 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs770866378, COSV65241472; called by muse, mutect2, varscan2
- FBXO7 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV56680270; called by muse, mutect2
- FBXW7 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV55938825; called by muse, mutect2, varscan2
- FCGR3B | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54211122; called by mutect2, varscan2
- FCMR | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV65568785; called by muse, mutect2, varscan2
- FCRL5 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV62517875; called by muse, mutect2, varscan2
- FCRLA | c.214del p.E72Rfs*4 (on ENST00000367959; = p.E49Rfs*4 on NM_032738.4) | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV99376298; called by mutect2, pindel, varscan2
- FER1L6 | c.4921G>C p.D1641H | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67551823; called by muse, mutect2
- FHL5 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV58739423; called by muse, mutect2, varscan2
- FIBIN | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.251); catalogued as COSV59413279; called by muse, mutect2, varscan2
- FKBP10 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54056891; called by muse, mutect2, varscan2
- FLG | c.3295C>A p.H1099N | Missense Mutation (SNP) | VAF 114/790 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV64245469; called by muse, mutect2, varscan2
- FLNB | c.291C>A p.I97= | Splice Region (SNP) | VAF 17/187 reads (9%) | catalogued as COSV55873303, COSV55887697, COSV55888700; called by muse, mutect2
- FLNC | c.4614T>G p.D1538E | Missense Mutation (SNP) | VAF 84/602 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV57961076; called by muse, mutect2, varscan2
- FMNL1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs565193966, COSV100056596, COSV100057143, COSV58958238; called by muse, mutect2, varscan2
- FOLH1 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.088); catalogued as COSV57045513, COSV57053520; called by muse, mutect2, varscan2
- FOXH1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371033241; called by muse, mutect2, varscan2
- FOXL2 | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM082717, COSV57729034; called by muse, mutect2
- FOXP2 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV63490844; called by muse, mutect2, varscan2
- FOXP4 | c.1274C>G p.P425R (on ENST00000307972 / NM_001012426.1; = p.P412R on NM_138457.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.25); catalogued as COSV57222544; called by muse, mutect2, varscan2
- FRAS1 | c.9866C>T p.P3289L | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53631591; called by muse, mutect2, varscan2
- FRAS1 | c.10249G>A p.D3417N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.326); catalogued as rs373601771; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRG1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV57005407, COSV99904141; called by muse, mutect2, varscan2
- FSTL5 | c.1303A>G p.R435G | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV60214854; called by muse, mutect2, varscan2
- FTH1 | c.414C>A p.Y138* | Nonsense Mutation (SNP) | VAF 12/75 reads (16%) | catalogued as COSV56446169; called by muse, mutect2, varscan2
- FTO | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 63/225 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1322897154, COSV67113221; called by muse, mutect2, varscan2
- FUBP3 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60515733; called by muse, mutect2, varscan2
- GABPA | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100702533; called by mutect2, varscan2
- GABRA1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50112670; called by muse, mutect2, varscan2
- GABRA5 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59483499; called by muse, mutect2, varscan2
- GABRB3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54665245; called by muse, mutect2, varscan2
- GABRP | c.909C>G p.I303M | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54664472; called by muse, mutect2, varscan2
- GALNTL6 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71830621; called by muse, mutect2, varscan2
- GDA | c.692A>T p.K231I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV52996100; called by muse, mutect2, varscan2
- GIMAP1 | c.578C>A p.T193N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV100211971, COSV56189224; called by muse, mutect2, varscan2
- GIMAP8 | c.877T>A p.W293R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230777, COSV56232957; called by muse, mutect2, varscan2
- GIPR | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 12/116 reads (10%) | catalogued as COSV54425429; called by muse, mutect2
- GJA8 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53789809, COSV53790725; called by muse, mutect2, varscan2
- GLRA4 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as rs760985980, COSV60327251, COSV60328111; called by muse, mutect2, varscan2
- GLS | c.413G>C p.S138T | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV57844233; called by muse, mutect2, varscan2
- GLYAT | c.305T>A p.L102* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV53540053; called by muse, mutect2, varscan2
- GLYR1 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV58928400; called by muse, mutect2, varscan2
- GMEB2 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56608143; called by muse, mutect2, varscan2
- GNAI1 | c.392G>T p.W131L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100650636; called by muse, mutect2
- GNAI1 | c.393G>T p.W131C | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650640; called by muse, mutect2
- GNB3 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV51835146; called by muse, mutect2, varscan2
- GOLGA3 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV52638862; called by muse, mutect2, varscan2
- GORASP2 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1327788975, COSV52203150; called by muse, mutect2, varscan2
- GOT2 | c.613A>T p.S205C | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55332559; called by muse, mutect2, varscan2
- GPATCH2L | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV55050246; called by muse, varscan2
- GPNMB | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs367885589, COSV51699874; called by muse, mutect2, varscan2
- GPR139 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58504111; called by muse, mutect2, varscan2
- GPR25 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV58498818; called by muse, mutect2, varscan2
- GPR50 | c.1207C>A p.H403N | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.035); catalogued as COSV54441460; called by muse, mutect2, varscan2
- GPR83 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.026); catalogued as rs1357234154, COSV54719956; called by muse, mutect2, varscan2
- GPRASP1 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs774872818, COSV64356160; called by muse, mutect2, varscan2
- GPRC5C | c.201G>T p.W67C (on ENST00000652232; = p.W22C on NM_018653.4) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.579); catalogued as COSV61236771; called by muse, mutect2, varscan2
- GPSM1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs782295639, COSV52518160; called by muse, mutect2, varscan2
- GRHPR | c.741C>A p.D247E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58944371; called by muse, mutect2, varscan2
- GRIA1 | c.2661G>C p.M887I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV53595997, COSV99602417; called by mutect2, varscan2
- GRIA2 | c.1271C>G p.S424C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52399730, COSV99644334; called by muse, mutect2, varscan2
- GRIA2 | c.1830C>G p.C610W | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99643196, COSV99645991; called by muse, mutect2, varscan2
- GRIA2 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1553956958, COSV52398829; ClinVar: not provided; called by muse, mutect2, varscan2
- GRID2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV56238729; called by muse, mutect2, varscan2
- GRXCR1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV67673366, COSV67673907; called by muse, mutect2
- GRXCR2 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100939995, COSV65061600; called by muse, mutect2, varscan2
- GSR | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV55322155, COSV99645500; called by muse, mutect2, varscan2
- GUCY1A1 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 9/96 reads (9%) | catalogued as COSV56654647, COSV56656838; called by muse, mutect2
- H3C13 | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58944655; called by muse, mutect2, varscan2
- H3C7 | c.166C>G p.Q56E | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV55100502; called by muse, mutect2
- HCFC1 | c.2853G>T p.M951I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as COSV60075511; called by muse, mutect2, varscan2
- HCN1 | c.2095T>G p.Y699D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.184); catalogued as COSV57527244, COSV57532691; called by muse, mutect2, varscan2
- HDAC4 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV61872028; called by muse, mutect2, varscan2
- HEATR1 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as COSV63979518, COSV63979583; called by muse, mutect2, varscan2
- HELB | c.2717G>T p.R906L | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56075046; called by muse, mutect2, varscan2
- HEPACAM2 | c.208T>A p.F70I (on ENST00000394468 / NM_001039372.4; = p.F58I on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.915); catalogued as COSV59062357; called by muse, mutect2, varscan2
- HEPH | c.194A>T p.D65V (on ENST00000343002; = p.D119V on NM_138737.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV57968802; called by muse, mutect2, varscan2
- HERC2 | c.6694A>G p.T2232A | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs768011315, COSV55340594; called by muse, mutect2, varscan2
- HIPK3 | c.3280C>G p.H1094D | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs141714879, COSV57561588, COSV57564462; called by muse, mutect2, varscan2
- HMCN1 | c.6016C>A p.L2006M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54923839; called by muse, mutect2, varscan2
- HMCN1 | c.8290G>T p.V2764F | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54923853; called by muse, mutect2, varscan2
- HMCN1 | c.12319C>G p.P4107A | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV54923865, COSV99635547; called by muse, mutect2, varscan2
- HMCN1 | c.12544G>A p.E4182K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.994); catalogued as rs968536996, COSV54923878; called by muse, mutect2, varscan2
- HNRNPH1 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 36/249 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV100270589, COSV61487590, COSV61487822; called by muse, mutect2, varscan2
- HNRNPLL | c.547-2A>G p.X183_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | catalogued as COSV55368696; called by muse, mutect2, varscan2
- HRNR | c.1318G>T p.G440C | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64254076; called by muse, mutect2, varscan2
- HSD17B6 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV59107129; called by muse, mutect2, varscan2
- HSP90AA1 | c.2162G>T p.G721V | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV53490396; called by muse, mutect2
- HSPA12A | c.1113C>G p.F371L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV65023324; called by muse, mutect2, varscan2
- HSPG2 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV65930633; called by muse, mutect2, varscan2
- HTR4 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 19/286 reads (7%) | catalogued as COSV58800362, COSV99042223; called by muse, mutect2
- HYDIN | c.11600G>T p.G3867V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as COSV66640906; called by muse, mutect2, varscan2
- IBSP | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV56896639; called by muse, mutect2, varscan2
- IBSP | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV99883811; called by muse, mutect2, varscan2
- ICA1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV99655928; called by muse, mutect2
- IGHV1-46 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 53/263 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs782115511; called by muse, mutect2, varscan2
- IL12RB2 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV52025615; called by muse, mutect2, varscan2
- IL16 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 76/469 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57266458; called by muse, mutect2, varscan2
- INMT | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99185159; called by muse, mutect2
- INSL5 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58788467; called by muse, mutect2, varscan2
- INTS9 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68435354; called by muse, mutect2, varscan2
- IQUB | c.2310G>T p.E770D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV61241243; called by muse, mutect2, varscan2
- IRX1 | c.640C>G p.P214A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV57361334; called by muse, mutect2, varscan2
- ISLR | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV51434594, COSV99997520; called by muse, mutect2, varscan2
- ITGA4 | c.2147T>G p.I716R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV67898385; called by muse, mutect2, varscan2
- ITGB4 | c.717C>G p.I239M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52330153; called by muse, mutect2, varscan2
- ITGB4 | c.3826G>A p.D1276N | Missense Mutation (SNP) | VAF 65/533 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV52330167; called by muse, mutect2, varscan2
- ITIH4 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56576835; called by muse, mutect2
- JAKMIP1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs1160983376, COSV51540269; called by muse, mutect2, varscan2
- KARS1 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 85/358 reads (24%) | catalogued as COSV56693549; called by muse, mutect2, varscan2
- KBTBD3 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV73241551; called by muse, mutect2
- KBTBD4 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.114); catalogued as COSV55455686; called by muse, mutect2, varscan2
- KCMF1 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV69054452; called by muse, mutect2
- KCNA5 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV52907136; called by muse, mutect2, varscan2
- KCNAB2 | c.503-1G>C p.X168_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51238201; called by muse, mutect2
- KCND2 | c.623C>A p.P208Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV100472855, COSV58594547; called by muse, mutect2, varscan2
- KCNH5 | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV59769943; called by muse, mutect2, varscan2
- KCNIP1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs930562572, COSV101066941, COSV66179727; called by muse, mutect2, varscan2
- KCNJ3 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV54540809; called by muse, mutect2, varscan2
- KCNK9 | c.1008G>C p.E336D | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV57278730, COSV57285891; called by muse, mutect2, varscan2
- KCNQ4 | c.583G>T p.G195C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61274430; called by muse, mutect2
- KCNU1 | c.2486T>C p.I829T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV67758440; called by muse, mutect2
- KCTD16 | c.1215C>G p.I405M | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV72580074; called by muse, mutect2, varscan2
- KDM4C | c.3120C>A p.Y1040* | Nonsense Mutation (SNP) | VAF 29/251 reads (12%) | catalogued as COSV67189875; called by muse, mutect2, varscan2
- KDM5D | c.3206G>T p.R1069I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58736935; called by muse, mutect2, varscan2
- KIAA0100 | c.3709G>C p.E1237Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV66495289; called by muse, mutect2, varscan2
- KIAA0100 | c.3070+1G>T p.X1024_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as COSV66495296; called by muse, mutect2, varscan2
- KIAA1109 | c.2561T>C p.M854T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV52685307; called by muse, mutect2, varscan2
- KIAA1586 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV66056572; called by mutect2, varscan2
- KIF19 | c.1897T>C p.Y633H | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as COSV63430185; called by muse, mutect2, varscan2
- KIF1A | c.3304C>A p.H1102N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV57496368; called by muse, mutect2
- KIF5C | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as COSV68482793; called by muse, mutect2
- KIR2DL1 | c.924C>G p.C308W | Missense Mutation (SNP) | VAF 79/528 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs2916014, COSV52412738; called by muse, mutect2, varscan2
- KL | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.463); catalogued as COSV66309559, COSV66309662; called by muse, mutect2, varscan2
- KLHDC4 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs767482682, COSV54510212; called by muse, mutect2, varscan2
- KLHL38 | c.1417C>G p.P473A | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58088498; called by muse, mutect2, varscan2
- KPRP | c.1529C>A p.P510Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV64222470; called by muse, mutect2, varscan2
- KRCC1 | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs967231878, COSV61251939; called by muse, mutect2, varscan2
- KRR1 | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370067745; called by muse, mutect2, varscan2
- KRT26 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV59414278; called by muse, mutect2, varscan2
- KRT4 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV99543226; called by muse, mutect2, varscan2
- KRT72 | c.1311G>A p.R437= | Splice Region (SNP) | VAF 38/104 reads (37%) | catalogued as COSV53375567; called by muse, mutect2, varscan2
- KRT78 | c.569G>T p.C190F | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV58852856; called by muse, mutect2, varscan2
- KY | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.907); catalogued as COSV71018209; called by muse, mutect2
- LAMA2 | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV70352486; called by muse, mutect2, varscan2
- LANCL2 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 1193/1334 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs375166275; called by muse, mutect2, varscan2
- LCE1D | c.44A>T p.K15M | Missense Mutation (SNP) | VAF 45/258 reads (17%) | PolyPhen possibly damaging (0.584); catalogued as COSV58271407, COSV58271891; called by muse, mutect2, varscan2
- LCP1 | c.1503-1G>T p.X501_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100550008; called by muse, mutect2, varscan2
- LDHC | c.680G>T p.W227L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV55005291; called by muse, mutect2, varscan2
- LEPR | c.3403A>T p.K1135* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as COSV62750342; called by muse, mutect2, varscan2
- LETM1 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs1040223952, COSV57103100; called by muse, mutect2, varscan2
- LGALS9 | c.982G>T p.E328* (on ENST00000395473 / NM_009587.3; = p.E296* on NM_002308.4) | Nonsense Mutation (SNP) | VAF 78/480 reads (16%) | catalogued as COSV56349001, COSV56350208; called by muse, mutect2, varscan2
- LGI2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1560290136, COSV66122276; called by muse, mutect2, varscan2
- LHFPL5 | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64178399; called by muse, mutect2, varscan2
- LHX9 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV61330470; called by muse, mutect2, varscan2
- LIG1 | c.1936G>T p.V646L | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV54394251; called by muse, mutect2, varscan2
- LILRB1 | c.1823C>A p.P608H (on ENST00000427581; = p.P557H on NM_006669.6) | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61120524, COSV61121832; called by muse, varscan2
- LPA | c.3088G>T p.V1030F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.98); catalogued as COSV60306867; called by muse, mutect2, varscan2
- LRP2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.114); catalogued as COSV55565555; called by muse, mutect2, varscan2
- LRRC37B | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58953866; called by muse, mutect2, varscan2
- LRRC4C | c.1399G>T p.D467Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV53435703, COSV99539818; called by muse, varscan2
- LRRC4C | c.1398G>T p.Q466H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99539823; called by muse, varscan2
- LRRC56 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV54245000; called by muse, mutect2, varscan2
- LRRC7 | c.3585C>A p.S1195R (on ENST00000651989 / NM_001370785.2; = p.S1162R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV50540757; called by muse, mutect2
- LRRFIP2 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 14/149 reads (9%) | catalogued as COSV60869197; called by muse, mutect2, varscan2
- LRRIQ1 | c.1670T>C p.L557S | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV67835495; called by muse, mutect2, varscan2
- LRRIQ1 | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs937508149, COSV67835503; called by muse, mutect2
- LRRK1 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV52621830; called by muse, mutect2, varscan2
- LRRN2 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.681); catalogued as COSV65784391; called by muse, mutect2, varscan2
- LRRTM4 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69139221; called by muse, mutect2
- LRTM2 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs527284344, COSV54564410, COSV54564443, COSV99765395; called by muse, mutect2, varscan2
- LSMEM1 | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57196848; called by muse, mutect2, varscan2
- LUC7L2 | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54928709; called by muse, mutect2, varscan2
- LY75 | c.4363G>T p.G1455W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55110424; called by muse, varscan2
- LY9 | c.1283C>T p.T428I | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs771661917, COSV54436238; called by muse, mutect2, varscan2
- LYST | c.10407G>T p.W3469C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101090316; called by muse, mutect2, varscan2
- MACF1 | c.3395G>C p.R1132P | Missense Mutation (SNP) | VAF 17/85 reads (20%) | catalogued as COSV58390938; called by muse, mutect2, varscan2
- MACF1 | c.9826C>T p.L3276F | Missense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV57134349; called by muse, mutect2, varscan2
- MAGEB16 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as COSV101303291, COSV67874286; called by muse, mutect2, varscan2
- MAGEC1 | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV53578038, COSV99595775; called by muse, mutect2, varscan2
- MAGEC1 | c.2194C>A p.Q732K | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV53578051; called by muse, mutect2, varscan2
- MAGEL2 | c.2204G>T p.R735L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV58566777, COSV58568348; called by muse, mutect2, varscan2
- MAGOHB | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296344; called by muse, mutect2, varscan2
- MAML3 | c.2699C>A p.P900Q | Missense Mutation (SNP) | VAF 80/522 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.693); catalogued as COSV72209754; called by muse, mutect2, varscan2
- MANEA | c.1178G>T p.R393L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776851480, COSV100721674, COSV62589766; called by muse, mutect2, varscan2
- MAP2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV52301494; called by muse, mutect2, varscan2
- MAPK14 | c.448-1G>T p.X150_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV57697026; called by muse, mutect2, varscan2
- MAPKAP1 | c.1551G>C p.K517N (on ENST00000265960 / NM_001006617.3; = p.K481N on NM_024117.3) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56372063; called by muse, mutect2, varscan2
- MAPT | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV52244823; called by muse, mutect2, varscan2
- MARVELD2 | c.1470G>A p.M490I | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as rs1275009510, COSV57780309, COSV57781638; called by muse, mutect2, varscan2
- MAST2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1244604087, COSV63620337; called by muse, mutect2, varscan2
- MBD5 | c.2001G>C p.L667F | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.391); catalogued as COSV68698430; called by muse, mutect2, varscan2
- MBD5 | c.3658G>T p.G1220C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.421); catalogued as COSV68698432; called by muse, mutect2, varscan2
- MC2R | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100563207; called by muse, mutect2
- MED13L | c.4909G>T p.D1637Y | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV56125977; called by muse, mutect2, varscan2
- MEGF8 | c.5738C>T p.S1913F (on ENST00000251268 / NM_001271938.2; = p.S1846F on NM_001410.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as COSV52075474; called by muse, mutect2, varscan2
- MEN1 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV53640126; called by muse, mutect2, varscan2
- METTL26 | c.560A>T p.E187V | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.447); catalogued as COSV57011189; called by muse, mutect2, varscan2
- MFN1 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV54941444; called by muse, mutect2
- MGAM | c.3304G>T p.G1102C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV72075223; called by muse, mutect2, varscan2
- MGAT5B | c.1644T>A p.N548K (on ENST00000569840 / NM_001199172.2; = p.N546K on NM_144677.3) | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV56933584; called by muse, mutect2, varscan2
- MIA3 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV60515881; called by muse, mutect2, varscan2
- MIB1 | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV99839485; called by muse, mutect2
- MIB2 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.345); catalogued as rs773322327, COSV61756855, COSV61757902; called by muse, mutect2, varscan2
- MICALL2 | c.1724G>T p.S575I | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1388143469, COSV52517630; called by muse, mutect2, varscan2
- MKI67 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as COSV64075755; called by muse, mutect2
- MKRN3 | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58811254; called by muse, mutect2, varscan2
- MMP1 | c.631A>T p.N211Y | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59511137; called by muse, mutect2
- MMP20 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52777151; called by muse, mutect2, varscan2
- MOGAT2 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV52220805; called by muse, mutect2, varscan2
- MPPED1 | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as COSV61988373; called by muse, mutect2
- MRGPRD | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.383); catalogued as COSV58423779, COSV58423856; called by muse, mutect2, varscan2
- MROH8 | c.1871G>C p.R624T | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV54122755; called by muse, mutect2, varscan2
- MRPL15 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV52638283; called by muse, mutect2, varscan2
- MRPS12 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs772487012, COSV55498188; called by muse, mutect2, varscan2
- MRPS28 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV52563919; called by muse, mutect2, varscan2
- MRPS6 | c.171G>C p.Q57H | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.361); catalogued as COSV62972031; called by muse, mutect2, varscan2
- MRTFA | c.551T>A p.V184E | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62935252; called by muse, mutect2, varscan2
- MS4A14 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.12); catalogued as COSV55736763; called by muse, mutect2, varscan2
- MSL3 | c.1322G>A p.G441D (on ENST00000312196 / NM_078629.4; = p.G275D on NM_006800.4) | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV56494959; called by muse, mutect2, varscan2
- MTA3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV68135950; called by muse, mutect2
- MTCL1 | c.3884G>C p.R1295P (on ENST00000306329 / NM_001378206.1; = p.R976P on NM_015210.4) | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV60403626, COSV60409473, COSV60413105; called by muse, mutect2, varscan2
- MTERF2 | c.561G>A p.M187I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs569455354, COSV53528212, COSV99526763; called by muse, mutect2, varscan2
- MTO1 | c.417+1G>T p.X139_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100940566; called by muse, mutect2, varscan2
- MTOR | c.4395G>C p.K1465N | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); catalogued as COSV63875685; called by muse, mutect2
- MUC16 | c.38512T>G p.S12838A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.012); catalogued as COSV67481285; called by muse, mutect2, varscan2
- MUC16 | c.32544C>A p.D10848E | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.148); catalogued as COSV67481288; called by muse, mutect2, varscan2
- MUC16 | c.28832C>A p.A9611D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.381); catalogued as rs747684685, COSV101198914, COSV67481290; called by muse, mutect2, varscan2
- MUC17 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV60297461; called by muse, mutect2, varscan2
- MUC17 | c.2755C>A p.P919T | Missense Mutation (SNP) | VAF 114/637 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60297465; called by muse, varscan2
- MUC17 | c.5740A>T p.S1914C | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV60297479; called by muse, mutect2
- MUC5B | c.10862C>T p.A3621V | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.564); catalogued as rs1165585361, COSV71594330; called by muse, mutect2, varscan2
- MYH4 | c.4657G>T p.A1553S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV55123210, COSV99701315; called by muse, mutect2
- MYH6 | c.2039G>C p.R680P | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV62452989, COSV62455174; called by muse, mutect2, varscan2
- MYH7 | c.2907C>A p.H969Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV62521878; called by muse, mutect2, varscan2
- MYH8 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV67969701; called by muse, mutect2, varscan2
- MYL5 | c.521G>C p.*174Sext*? | Nonstop Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs371278586, COSV59140250, COSV59141261; called by muse, mutect2, varscan2
- MYO10 | c.1913A>T p.K638M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72563345; called by muse, mutect2
- MYO18B | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.393); catalogued as COSV59142680; called by muse, mutect2
- MYO1H | c.1016T>C p.I339T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751206013, COSV60447544, COSV60448881; called by muse, mutect2, varscan2
- MYO7B | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376693425, COSV67349974; called by muse, mutect2, varscan2
- MYOC | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV50676697; called by muse, mutect2
- MYOM3 | c.930G>A p.G310= | Splice Region (SNP) | VAF 8/69 reads (12%) | catalogued as rs1557613549, COSV58397809; called by muse, mutect2, varscan2
- MYT1L | c.1508A>T p.K503M | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67727367; called by muse, mutect2, varscan2
- N4BP2L2 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.707); catalogued as COSV57229397; called by muse, mutect2, varscan2
- NACA2 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV71713172; called by muse, mutect2, varscan2
- NASP | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV63114059; called by muse, varscan2
- NAV1 | c.4076T>C p.L1359P | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55222577; called by muse, mutect2, varscan2
- NAV3 | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57100154; called by muse, mutect2, varscan2
- NBEAL2 | c.1787A>C p.Q596P | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52761372; called by muse, mutect2
- NCKAP5 | c.4345G>T p.G1449* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV58462976; called by muse, mutect2
- NCOA6 | c.2511G>C p.Q837H | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV62866161; called by muse, mutect2, varscan2
- NDRG4 | c.725G>T p.G242V (on ENST00000570248 / NM_001378344.1; = p.G274V on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV50749790; called by muse, mutect2
- NEB | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.992); catalogued as COSV51441602; called by muse, mutect2
- NEIL2 | c.688G>T p.G230W | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52707464; called by muse, mutect2
- NETO2 | c.839G>T p.S280I | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV100292439, COSV57454723; called by muse, mutect2, varscan2
- NGFR | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV50803469; called by muse, mutect2, varscan2
- NIBAN1 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV62286684; called by muse, mutect2, varscan2
- NID1 | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 61/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51616252, COSV51625470; called by muse, mutect2, varscan2
- NINL | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV54006598; called by muse, mutect2, varscan2
- NKX6-1 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99880198; called by muse, mutect2
- NLRP2 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV54758360; called by muse, mutect2
- NLRP3 | c.981C>A p.D327E | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.173); catalogued as COSV60226149, COSV60229041; called by muse, mutect2, varscan2
- NLRP5 | c.2148G>C p.Q716H | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.719); catalogued as rs750243367, COSV66766395; called by muse, mutect2, varscan2
- NME6 | c.418G>C p.E140Q (on ENST00000415053; = p.E148Q on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56640870; called by muse, mutect2, varscan2
- NME8 | c.851C>A p.A284D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV99066911; called by muse, mutect2, varscan2
- NME9 | c.682C>T p.H228Y (on ENST00000333911 / NM_001349024.2; = p.H167Y on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV58621322; called by muse, mutect2, varscan2
- NOP56 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 32/205 reads (16%) | catalogued as COSV61390941; called by muse, mutect2, varscan2
- NOXRED1 | c.155+1G>T p.X52_splice | Splice Site (SNP) | VAF 109/384 reads (28%) | catalogued as COSV100033229; called by muse, mutect2, varscan2
- NPFFR2 | c.1203C>A p.Y401* | Nonsense Mutation (SNP) | VAF 17/81 reads (21%) | catalogued as COSV100440247, COSV58146856, COSV58152388; called by muse, mutect2, varscan2
- NPHP1 | c.2038G>C p.E680Q (on ENST00000393272 / NM_207181.4; = p.E681Q on NM_000272.5) | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100338056, COSV57210482; called by muse, mutect2, varscan2
- NPR1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV64142670; called by muse, mutect2, varscan2
- NPR1 | c.1587C>A p.S529R | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV64117915; called by muse, mutect2
- NPRL3 | c.1310G>T p.R437L (on ENST00000611875 / NM_001077350.3; = p.R412L on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.598); catalogued as COSV54737825, COSV54739184; called by muse, mutect2, varscan2
- NR1I3 | c.913C>T p.R305* (on ENST00000367982 / NM_001077480.3; = p.R301* on NM_005122.5) | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as rs769594436, COSV63468871; called by muse, mutect2, varscan2
- NR1I3 | c.118A>T p.S40C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV63468887; called by muse, mutect2, varscan2
- NRCAM | c.1727C>A p.S576Y (on ENST00000379028 / NM_001371124.1; = p.S570Y on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.435); catalogued as COSV61044167; called by muse, mutect2, varscan2
- NRG3 | c.1763T>A p.V588E (on ENST00000404547 / NM_001370084.1; = p.V564E on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/314 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.347); catalogued as COSV64575860; called by muse, mutect2, varscan2
- NRXN1 | c.2314G>C p.D772H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58476553; called by muse, mutect2
- NSD1 | c.2551G>C p.D851H | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV61780773; called by muse, mutect2
- NT5C1A | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.25); catalogued as rs1002733564, COSV52495683; called by muse, mutect2, varscan2
- NTM | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV66187500; called by muse, mutect2, varscan2
- NXF3 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV67704609; called by muse, mutect2, varscan2
- NXPH2 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55645329; called by muse, mutect2
- OBSL1 | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54726363; called by muse, mutect2, varscan2
- ODF1 | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53433661; called by mutect2, varscan2
- OGA | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63382614; called by muse, mutect2, varscan2
- OGDHL | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV65103807; called by muse, mutect2, varscan2
- OLR1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 31/255 reads (12%) | catalogued as COSV58872315; called by muse, mutect2, varscan2
- OPRK1 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs890331248, COSV55572641, COSV55572689; called by muse, mutect2
- OR10G8 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1195663573, COSV70909029; called by muse, mutect2, varscan2
- OR10H2 | c.862C>G p.P288A | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV59946659; called by muse, mutect2, varscan2
- OR10K2 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); catalogued as COSV59222128; called by muse, mutect2, varscan2
- OR10V1 | c.263T>A p.M88K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.218); catalogued as rs897263327, COSV55699924; called by muse, mutect2
- OR1J4 | c.743T>A p.V248E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61590128; called by muse, mutect2, varscan2
- OR2A7 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 8/202 reads (4%) | catalogued as COSV101512238; called by muse, mutect2
- OR2AK2 | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63557893; called by muse, mutect2, varscan2
- OR2M5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV63546649, COSV63546750; called by muse, varscan2
- OR2T4 | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63544713; called by muse, varscan2
- OR4C6 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100051885, COSV58605413; called by muse, mutect2, varscan2
- OR4D2 | c.617T>A p.L206Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73459828; called by muse, mutect2, varscan2
- OR51M1 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60785124; called by muse, mutect2, varscan2
- OR52I1 | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.383); catalogued as COSV56169355; called by muse, mutect2, varscan2
- OR52I2 | c.583C>A p.H195N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV57045751; called by muse, mutect2, varscan2
- OR5A1 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 76/519 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs998501521, COSV57377616; called by muse, mutect2, varscan2
- OR5B2 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56907644; called by muse, mutect2, varscan2
- OR5L1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs1565118088, COSV61734864; called by muse, mutect2, varscan2
- OR5L2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs267602980, COSV65723579; called by muse, mutect2, varscan2
- OR5T2 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs775554683, COSV57590346; called by muse, mutect2, varscan2
- OR6K2 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV62743972; called by muse, mutect2
- OR6N2 | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV59412376; called by muse, mutect2, varscan2
- OR6Q1 | c.712C>A p.R238S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56932524; called by muse, mutect2, varscan2
- OR8D2 | c.560T>G p.L187R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62488802; called by muse, mutect2, varscan2
- OR8G5 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100422673; called by muse, mutect2
- OR8K1 | c.893T>A p.L298Q | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV54403747; called by muse, mutect2, varscan2
- OR8K5 | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV57890223; called by muse, mutect2, varscan2
- OSBPL6 | c.350del p.K117Sfs*18 | Frame Shift Del (DEL) | VAF 42/260 reads (16%) | catalogued as COSV51923163; called by mutect2, pindel, varscan2
- OSBPL7 | c.398G>T p.W133L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50112561; called by muse, mutect2, varscan2
- OTOA | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53760493; called by muse, mutect2, varscan2
- OXSR1 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV61259838; called by muse, mutect2, varscan2
- P2RY13 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs371578438, COSV56366958; called by muse, mutect2, varscan2
- PAGE1 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65998260, COSV65998452; called by muse, mutect2, varscan2
- PALLD | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV54989002; called by muse, mutect2, varscan2
- PALLD | c.3349G>C p.D1117H (on ENST00000505667 / NM_001166108.2; = p.D1100H on NM_016081.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54989020, COSV99823517; called by muse, mutect2, varscan2
- PAPPA2 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100867170; called by muse, mutect2, varscan2
- PAPPA2 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 15/149 reads (10%) | catalogued as COSV100867174, COSV62782048; called by muse, mutect2, varscan2
- PARP12 | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV54936114; called by muse, mutect2
- PASD1 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs754453250, COSV64855674, COSV64856719; called by muse, mutect2, varscan2
- PATZ1 | c.508G>C p.A170P | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV53230593; called by muse, mutect2, varscan2
- PCDH10 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52096060, COSV52100038; called by muse, mutect2, varscan2
- PCDH15 | c.5060C>A p.P1687H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV100227792; called by muse, mutect2, varscan2
- PCDHA1 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV65375946; called by muse, mutect2, varscan2
- PCDHB1 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs782718422, COSV60632390; called by muse, mutect2
- PCDHB2 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50603345; called by muse, mutect2, varscan2
- PCDHB4 | c.2191T>C p.F731L | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV52025152; called by muse, mutect2, varscan2
- PCDHB8 | c.2059C>A p.L687I | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV50796903; called by muse, mutect2, varscan2
- PCDHGB1 | c.858C>A p.S286R | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV53997832; called by muse, mutect2
- PCDHGB2 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.079); catalogued as COSV99547172; called by muse, mutect2
- PCGF3 | c.624G>C p.E208D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as COSV62860296; called by muse, mutect2, varscan2
- PCK1 | c.1530G>T p.K510N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV60130058; called by muse, mutect2, varscan2
- PCNX1 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs756216529, COSV53098796; called by muse, mutect2, varscan2
- PCOLCE | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56158638; called by muse, mutect2, varscan2
- PCYOX1 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52477596; called by muse, mutect2, varscan2
- PDCD2L | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55826111; called by muse, mutect2, varscan2
- PDE3A | c.2770-2A>T p.X924_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100762812; called by muse, mutect2, varscan2
- PDE3A | c.2770-1G>T p.X924_splice | Splice Site (SNP) | VAF 11/75 reads (15%) | catalogued as COSV100762814, COSV99075623; called by muse, mutect2, varscan2
- PDE4DIP | c.3055G>C p.E1019Q | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.07); catalogued as COSV57717116; called by muse, mutect2
- PDE8B | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99367615; called by muse, mutect2
- PDGFRL | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52414241; called by muse, mutect2, varscan2
- PDHA2 | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as COSV54780729, COSV99757314; called by muse, mutect2, varscan2
- PEG3 | c.494G>T p.W165L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV55641841; called by muse, mutect2, varscan2
- PGAM4 | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100431723; called by muse, mutect2, varscan2
- PGBD2 | c.1670A>T p.Q557L | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV61400729; called by muse, mutect2, varscan2
- PHACTR1 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60675573; called by muse, mutect2
- PHACTR4 | c.602C>G p.S201C (on ENST00000373839 / NM_001350159.2; = p.S211C on NM_023923.4) | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV65784767; called by muse, mutect2, varscan2
- PHF24 | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV54275862; called by muse, mutect2, varscan2
- PHF8 | c.772G>C p.E258Q (on ENST00000357988 / NM_001184896.1; = p.E222Q on NM_015107.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV57685433; called by muse, mutect2, varscan2
- PHLDB2 | c.3533C>A p.A1178E (on ENST00000393925 / NM_001134439.2; = p.A1135E on NM_145753.2) | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV67314399, COSV67315338; called by muse, mutect2, varscan2
- PI16 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs1330714911, COSV65448511; called by muse, mutect2
- PI4KB | c.562G>A p.E188K (on ENST00000368873 / NM_001369623.1; = p.E200K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV55019972; called by muse, mutect2, varscan2
- PIAS3 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65171798; called by muse, mutect2, varscan2
- PIGG | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV56320177; called by muse, mutect2, varscan2
- PIK3R3 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV53109858; called by muse, mutect2
- PIK3R4 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs775405232, COSV63242838; called by muse, mutect2, varscan2
- PIM3 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62260044; called by muse, mutect2
- PIWIL4 | c.1915G>T p.V639L | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54409507, COSV54411206; called by muse, mutect2, varscan2
- PKD1 | c.11321G>T p.G3774V (on ENST00000262304 / NM_001009944.3; = p.G3773V on NM_000296.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as COSV51916578; called by muse, mutect2
- PKD2L1 | c.2198C>G p.S733* | Nonsense Mutation (SNP) | VAF 31/169 reads (18%) | catalogued as COSV58396839; called by muse, mutect2, varscan2
- PLEKHA4 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV54362089, COSV54364897; called by muse, mutect2, varscan2
- PLEKHG5 | c.415G>T p.E139* (on ENST00000400915 / NM_001042663.3; = p.E102* on NM_020631.6) | Nonsense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as COSV61704638; called by muse, mutect2, varscan2
- PLG | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV51984901; called by muse, mutect2, varscan2
- PLG | c.2059C>G p.P687A | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57519077; called by muse, mutect2, varscan2
- PLXNA2 | c.4486G>T p.E1496* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | catalogued as COSV65443256; called by muse, mutect2, varscan2
- PMM1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.576); catalogued as rs753378596, COSV53447991; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV62612789; called by muse, mutect2, varscan2
- POLQ | c.643G>T p.V215L | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV51757833; called by muse, mutect2
- POLR3E | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV55402360; called by muse, mutect2, varscan2
- POLR3E | c.515A>C p.Q172P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.065); catalogued as COSV55402370; called by muse, varscan2
- POLR3E | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100242414; called by muse, mutect2, varscan2
- POLR3F | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781750604, COSV52754886; called by muse, mutect2, varscan2
- POMC | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV53035414; called by muse, mutect2, varscan2
- POP4 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55677031; called by muse, mutect2, varscan2
- PPFIA1 | c.2576A>T p.Q859L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV54138882; called by muse, varscan2
- PPP1R15B | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV65816264; called by muse, mutect2, varscan2
- PPP2R3A | c.2795C>G p.S932* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53868179, COSV99387639; called by muse, mutect2, varscan2
- PRAME | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as rs751175197, COSV67162210; called by muse, mutect2
- PRB1 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV53705633; called by muse, mutect2, varscan2
- PRICKLE2 | c.2364C>G p.F788L (on ENST00000295902; = p.F732L on NM_198859.4) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV55769813, COSV55773055; called by muse, mutect2, varscan2
- PRICKLE2 | c.1270G>T p.D424Y (on ENST00000295902; = p.D368Y on NM_198859.4) | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55766158, COSV55769414; called by muse, mutect2
- PRKACB | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65763849; called by muse, mutect2, varscan2
- PRKCA | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99436265; called by muse, mutect2
- PRKCB | c.1293C>A p.H431Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.94); PolyPhen benign (0.108); catalogued as COSV100335414; called by muse, mutect2, varscan2
- PRKCSH | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52952894; called by muse, mutect2, varscan2
- PROSER1 | c.2000G>A p.S667N | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV61488871; called by muse, mutect2, varscan2
- PRPF31 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV58086337, COSV58087142; called by muse, mutect2, varscan2
- PRSS55 | c.995G>T p.S332I | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as rs1478509877, COSV60808936; called by muse, mutect2, varscan2
- PRSS8 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV54898233; called by muse, mutect2, varscan2
- PSEN2 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV60917488; called by muse, mutect2, varscan2
- PSG1 | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 61/573 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755813777, COSV54954344; called by muse, mutect2, varscan2
- PSG3 | c.645T>A p.Y215* | Nonsense Mutation (SNP) | VAF 90/701 reads (13%) | catalogued as COSV59505932; called by muse, mutect2, varscan2
- PSG5 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV61654835; called by muse, mutect2, varscan2
- PSME4 | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV66366646; called by muse, mutect2, varscan2
- PSTK | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as COSV64398814; called by muse, mutect2, varscan2
- PTCHD3 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.225); catalogued as COSV71257165; called by muse, mutect2, varscan2
- PTGIS | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV54839234; called by muse, mutect2, varscan2
- PTGS1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 65/365 reads (18%) | catalogued as COSV56293710; called by muse, mutect2, varscan2
- PTK2B | c.1596G>C p.Q532H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1268218695, COSV100593292, COSV100594033, COSV57762381; called by muse, mutect2, varscan2
- PTPRD | c.2774T>G p.L925R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV61925667, COSV61968854; called by muse, mutect2, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs772722517, COSV99560265; called by mutect2, varscan2
- PUM3 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1401411520, COSV65896862; called by muse, mutect2, varscan2
- PURG | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.039); catalogued as COSV53304413; called by muse, mutect2, varscan2
- PYDC2 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV72921404; called by muse, mutect2
- PYGL | c.1837G>C p.G613R | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53587560; called by muse, mutect2, varscan2
- PYHIN1 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV63723465; called by muse, mutect2, varscan2
- RAB33B | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV59777851; called by mutect2, varscan2
- RAD51AP2 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV67588643; called by muse, mutect2, varscan2
- RAG2 | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57558847; called by muse, mutect2, varscan2
- RALBP1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV50037397; called by muse, mutect2, varscan2
- RAMP2 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV53823343; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 66/380 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs959378939, COSV54584092; called by muse, mutect2, varscan2
- RASGRP3 | c.646C>A p.Q216K | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as COSV67821255, COSV67823885; called by muse, mutect2
- RB1CC1 | c.4511G>C p.G1504A | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50261842; called by muse, mutect2
- RBL1 | c.2987T>G p.L996R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as COSV60331864; called by muse, mutect2, varscan2
- RBM44 | c.1159G>A p.E387K (on ENST00000611254; = p.E1021K on NM_001080504.2) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs1306271354, COSV57632040; called by muse, mutect2
- RBPJ | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV60754632; called by muse, mutect2
- RCOR1 | c.1042G>T p.V348F | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs765378630, COSV51770749; called by muse, mutect2, varscan2
- RELN | c.1787A>T p.N596I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59022731; called by muse, mutect2, varscan2
- RERE | c.3848C>G p.P1283R | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV61946968; called by muse, mutect2, varscan2
- RFLNB | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61239742; called by muse, mutect2, varscan2
- RFX1 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413161203, COSV54332209; called by muse, mutect2
- RHBG | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV54802093, COSV54808009; called by muse, mutect2, varscan2
- RIMS4 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65720338; called by muse, mutect2, varscan2
- RNF113A | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65097663; called by muse, mutect2, varscan2
- RNF14 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 38/397 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV61662664; called by muse, mutect2
- ROCK1 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV67697831; called by muse, mutect2, varscan2
- ROS1 | c.1009G>C p.V337L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.124); catalogued as COSV63859178; called by muse, mutect2, varscan2
- RP1 | c.5551C>T p.H1851Y | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.014); catalogued as COSV55122480; called by muse, mutect2, varscan2
- RP1L1 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV61446820; called by muse, mutect2
- RPS6KC1 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV65301601; called by muse, mutect2, varscan2
- RRAGC | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV65931841; called by muse, mutect2, varscan2
- RTL4 | c.663C>G p.D221E | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV61206989; called by muse, mutect2, varscan2
- RYR1 | c.11216G>T p.G3739V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV62104847, COSV62105892; called by muse, mutect2, varscan2
- RYR2 | c.2693T>C p.I898T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63702172; called by muse, mutect2, varscan2
- RYR2 | c.13150C>A p.L4384M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1008031175, COSV63702192; called by muse, mutect2, varscan2
- RYR2 | c.14184G>T p.M4728I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV63692044; called by muse, mutect2, varscan2
- SALL1 | c.1117T>A p.S373T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV51761705; called by muse, mutect2, varscan2
- SALL1 | c.756C>G p.H252Q | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs774698705, COSV51761721, COSV99069422; called by muse, mutect2
- SBK2 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as COSV100705253, COSV60014854; called by muse, mutect2, varscan2
- SCAF8 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65793111; called by muse, mutect2, varscan2
- SCN10A | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.876); catalogued as COSV71862321; called by muse, mutect2, varscan2
- SCN2A | c.5854G>A p.D1952N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1163504197, COSV99333546; called by muse, mutect2, varscan2
- SCN3A | c.3498A>T p.E1166D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.1); catalogued as COSV51818498; called by muse, mutect2, varscan2
- SDS | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV55108168; called by muse, mutect2, varscan2
- SELE | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.606); catalogued as COSV60976937; called by muse, mutect2, varscan2
- SEMA3C | c.1930A>T p.I644F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.392); catalogued as COSV54852566; called by muse, mutect2, varscan2
- SEMA4F | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60284523; called by muse, mutect2, varscan2
- SEMA4F | c.1594T>C p.W532R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60284529; called by muse, mutect2, varscan2
- SEMA5A | c.2936C>G p.S979C | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.894); catalogued as rs1181687986, COSV66801194; called by muse, mutect2, varscan2
- SEMA5A | c.2210T>A p.L737Q | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV66801198; called by muse, mutect2
- SEMA5A | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as COSV101228732; called by muse, mutect2, varscan2
- SEMA5B | c.2851G>A p.G951R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1466335803, COSV52104147; called by muse, mutect2, varscan2
- SEMG2 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.396); catalogued as COSV65647763; called by muse, mutect2, varscan2
- SEPHS1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs1468296697, COSV59259782; called by muse, mutect2, varscan2
- SERBP1 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV63413997; called by muse, mutect2, varscan2
- SERPINA3 | c.1147C>A p.L383I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.145); catalogued as COSV67586771; called by muse, mutect2, varscan2
- SERPINB13 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV54029272; called by muse, mutect2, varscan2
- SEZ6 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.98); catalogued as COSV57979908, COSV57983301; called by muse, mutect2, varscan2
- SFR1 | c.251C>G p.S84* (on ENST00000369727 / NM_001002759.1; = p.S71* on NM_145247.4) | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV60479665; called by muse, mutect2, varscan2
- SGCZ | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs767275078, COSV66001834, COSV66030907; called by muse, mutect2, varscan2
- SGSM1 | c.3254C>G p.S1085C (on ENST00000400359 / NM_001039948.4; = p.S1024C on NM_133454.3) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68512206; called by muse, mutect2
- SH2D2A | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs986774403, COSV63884750, COSV63885170; called by muse, mutect2, varscan2
- SH2D2A | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV63885178; called by muse, mutect2, varscan2
- SH3D19 | c.2261G>C p.G754A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58792396; called by muse, mutect2, varscan2
- SH3PXD2B | c.2711C>A p.S904Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV61127018, COSV61128660; called by muse, mutect2, varscan2
- SHANK1 | c.3436G>T p.A1146S | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs777507884, COSV53256235, COSV53257538; called by muse, mutect2, varscan2
- SHC2 | c.1392G>T p.Q464H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99199219; called by muse, mutect2, varscan2
- SHOC2 | c.973-1G>T p.X325_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54621543; called by muse, mutect2, varscan2
- SIGLEC1 | c.3460C>A p.P1154T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV52468988, COSV99170896; called by muse, mutect2, varscan2
572 further variants in this file (245 protein-altering or splice-affecting, 293 silent, 34 other) are not listed here.
